Somatic mutation profile of tumor specimen HCM-BROD-0200-C71-01A (aliquot HCM-BROD-0200-C71-01A-11D-A78T-36) from HCMI case HCM-BROD-0200-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.2 years (27,463 days).
Specimen HCM-BROD-0200-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdaa70ea-4ad5-4f7c-951b-d168165706d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0200-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0200-C71-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e684b2a5-776b-495a-94b1-671ae1a7936a

The open-access MAF lists 95 somatic variants for this specimen: 60 protein-altering or splice-affecting, 21 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 21, Intron 8, Nonsense Mutation 3, Splice Site 2, 5'UTR 2, 3'UTR 2, RNA 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GABRA1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 56/311 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs727503940, COSV50119921, COSV99195708; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PDGFRA | c.704G>C p.C235S | Missense Mutation (SNP) | VAF 1433/2179 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57264163, COSV57266901, COSV57267810; called by muse, mutect2, varscan2
- ALPG | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 67/365 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs770957226, COSV54966433; called by muse, mutect2, varscan2
- ANKFY1 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 30/109 reads (28%) | catalogued as rs779067805; called by muse, mutect2, varscan2
- ARFGEF3 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1326151522, COSV52472440; called by muse, mutect2, varscan2
- ATP4A | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.888); catalogued as rs144661332; called by muse, mutect2, varscan2
- CACNA1S | c.3808G>A p.V1270M | Missense Mutation (SNP) | VAF 81/406 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749105028; called by muse, mutect2, varscan2
- CIT | c.2294C>T p.A765V | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs749312866; called by muse, mutect2, varscan2
- COL11A1 | c.4793G>A p.G1598D | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100614254; called by muse, mutect2, varscan2
- CUL3 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs760276064, COSV52369144; called by muse, mutect2, varscan2
- ELFN2 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as rs376827195; called by muse, mutect2, varscan2
- GCGR | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 59/287 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.903); catalogued as rs947813160; called by muse, mutect2, varscan2
- GDF10 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs781814156; called by muse, mutect2, varscan2
- KCNS2 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs781697576, COSV54637693; called by muse, mutect2, varscan2
- KLHL7 | c.881G>A p.R294H (on ENST00000339077 / NM_001031710.3; = p.R246H on NM_018846.5) | Missense Mutation (SNP) | VAF 66/539 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs1043587892, COSV59165446; called by muse, mutect2, varscan2
- KPRP | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as rs1445616839, COSV64221535; called by muse, mutect2, varscan2
- LCE1F | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 79/399 reads (20%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.026); catalogued as rs553837591, COSV57668776; called by muse, mutect2, varscan2
- MGAM | c.4417G>A p.G1473S | Missense Mutation (SNP) | VAF 94/681 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as rs758607719; called by muse, mutect2, varscan2
- NDRG1 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); catalogued as rs777244818; called by muse, mutect2, varscan2
- NEUROD6 | c.966C>A p.S322R | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as COSV51772590; called by muse, mutect2
- OR7G2 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as rs1220167316; called by muse, mutect2, varscan2
- P2RY8 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 54/273 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.825); catalogued as rs1382755800; called by muse, mutect2, varscan2
- PAN2 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 95/452 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99228196; called by muse, mutect2, varscan2
- PIBF1 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 29/132 reads (22%) | catalogued as rs374837848; called by muse, mutect2, varscan2
- PKHD1 | c.6818C>T p.T2273M | Missense Mutation (SNP) | VAF 33/271 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs375784210; called by muse, mutect2, varscan2
- PPP1R3E | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1213719289; called by muse, mutect2, varscan2
- PTEN | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 85/289 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1564830084, COSV64294745, COSV64299772; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTP4A2 | c.164T>C p.V55A | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs1011744907; called by muse, mutect2, varscan2
- RBM11 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs528749430; called by muse, mutect2, varscan2
- SCN9A | c.596+1G>A p.X199_splice | Splice Site (SNP) | VAF 36/181 reads (20%) | catalogued as rs201560701, COSV57606863, COSV57616568; called by muse, mutect2, varscan2
- SCUBE1 | c.1276G>A p.G426S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as rs772360095, COSV100683408; called by muse, mutect2
- STAP1 | c.376del p.Q126Kfs*10 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as COSV55326539, COSV55327490; called by mutect2, pindel, varscan2
- SYNDIG1 | c.407T>A p.L136H | Missense Mutation (SNP) | VAF 82/293 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as COSV65234737; called by muse, varscan2
- TAS2R1 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs767333394; called by muse, mutect2, varscan2
- TEX2 | c.3329G>A p.R1110H (on ENST00000583097 / NM_001288733.2; = p.R1117H on NM_018469.5) | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs778477556, COSV51979048, COSV51982534; called by muse, mutect2, varscan2
- TLR5 | c.626A>G p.Y209C | Missense Mutation (SNP) | VAF 93/442 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100643420; called by muse, mutect2, varscan2
- TRDN | c.1128G>T p.K376N | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV62121110, COSV62133905; called by muse, mutect2, varscan2
- TRIM29 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 86/370 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as COSV100531800; called by muse, mutect2, varscan2
- TTN | c.29161G>T p.V9721L (on ENST00000591111; = p.V8794L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/345 reads (15%) | PolyPhen benign (0.419); catalogued as COSV59983264; called by muse, mutect2, varscan2
- USP37 | c.2753C>T p.A918V | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.063); catalogued as rs780874508, COSV50285389; called by muse, mutect2, varscan2
- XDH | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 98/466 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs780502467; called by muse, mutect2, varscan2
- ZFR2 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs558302396; called by muse, mutect2, varscan2
- ZNF578 | c.1137G>A p.M379I | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs777923491; called by muse, mutect2, varscan2
- BNC2 | c.1178T>C p.V393A | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CDH11 | c.1078A>G p.S360G | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DPF2 | c.515A>G p.Y172C | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DSCAM | c.4709G>T p.G1570V | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRM3 | c.1719A>T p.E573D | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- HEMGN | c.1403T>C p.I468T | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KDM7A | c.358A>G p.R120G | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- MGAT3 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- MS4A15 | c.498+1G>T p.X166_splice (on ENST00000405633 / NM_001098835.2; = p.X73_splice on NM_152717.3) | Splice Site (SNP) | VAF 26/128 reads (20%) | called by muse, mutect2, varscan2
- OR2F2 | c.806T>A p.L269H | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PKHD1 | c.138G>T p.E46D | Missense Mutation (SNP) | VAF 58/303 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC38A8 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 68/346 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPTBN1 | c.546G>A p.W182* | Nonsense Mutation (SNP) | VAF 16/99 reads (16%) | called by muse, mutect2, varscan2
- TMEFF2 | c.965T>A p.I322N | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPK1 | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- VPS8 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZBBX | c.2141C>A p.T714N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ADAP1 | c.177C>T p.S59= | Silent (SNP) | VAF 38/283 reads (13%) | catalogued as rs1397009559; called by muse, mutect2, varscan2
- APLP1 | c.1620G>A p.K540= (on ENST00000221891 / NM_001024807.3; = p.K539= on NM_005166.4) | Silent (SNP) | VAF 69/303 reads (23%) | catalogued as rs1431497657; called by muse, mutect2, varscan2
- ATP10B | c.1044C>T p.F348= | Silent (SNP) | VAF 30/141 reads (21%) | catalogued as rs541851085, COSV58781352; called by muse, mutect2, varscan2
- CLRN1 | c.168G>A p.K56= | Silent (SNP) | VAF 30/199 reads (15%) | called by muse, mutect2, varscan2
- EMP2 | c.456C>T p.C152= | Silent (SNP) | VAF 20/94 reads (21%) | called by muse, mutect2, varscan2
- FLNB | c.852C>T p.A284= | Silent (SNP) | VAF 55/266 reads (21%) | catalogued as rs765017696; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FNDC1 | c.2403G>A p.A801= | Silent (SNP) | VAF 46/200 reads (23%) | catalogued as COSV51930088; called by muse, mutect2, varscan2
- HECW1 | c.1650C>T p.C550= | Silent (SNP) | VAF 56/297 reads (19%) | catalogued as rs763924846, COSV67833539; called by muse, mutect2, varscan2
- HRH2 | c.546C>T p.Y182= | Silent (SNP) | VAF 43/203 reads (21%) | catalogued as rs772344735; called by muse, mutect2, varscan2
- IL24 | c.297C>T p.N99= | Silent (SNP) | VAF 37/270 reads (14%) | catalogued as rs761273178, COSV54321632; called by muse, mutect2, varscan2
- LARS1 | c.1032C>T p.G344= (on ENST00000394434 / NM_020117.11; = p.G317= on NM_016460.3) | Silent (SNP) | VAF 39/205 reads (19%) | catalogued as rs749791589, COSV50974416; called by muse, mutect2, varscan2
- SLC2A14 | c.75G>C p.P25= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs777834662; called by muse, mutect2, varscan2
- SPANXN2 | c.183G>A p.T61= | Silent (SNP) | VAF 75/171 reads (44%) | catalogued as rs782774590, COSV65127684; called by muse, mutect2, varscan2
- SPTA1 | c.1674C>T p.D558= | Silent (SNP) | VAF 77/373 reads (21%) | catalogued as rs780161347, COSV63750189; called by muse, mutect2, varscan2
- SSTR5 | c.306G>A p.A102= | Silent (SNP) | VAF 100/440 reads (23%) | catalogued as rs1354513472; called by muse, mutect2, varscan2
- TPBG | c.93G>A p.S31= | Silent (SNP) | VAF 45/202 reads (22%) | called by muse, mutect2, varscan2
- TPSD1 | c.174C>T p.R58= | Silent (SNP) | VAF 31/193 reads (16%) | catalogued as rs778229260, COSV52974243; called by muse, mutect2, varscan2
- TRAV25 | c.117G>A p.T39= | Silent (SNP) | VAF 23/110 reads (21%) | called by muse, mutect2, varscan2
- TSSK6 | c.759C>T p.S253= | Silent (SNP) | VAF 60/227 reads (26%) | catalogued as rs760900701; called by muse, mutect2, varscan2
- UCKL1 | c.57G>A p.T19= | Silent (SNP) | VAF 47/200 reads (24%) | catalogued as rs535689162; called by muse, mutect2, varscan2
- UGT2B17 | c.1362G>A p.P454= | Silent (SNP) | VAF 44/186 reads (24%) | catalogued as rs746870450; called by muse, mutect2, varscan2
- CCDC40 | c.1562+1913G>A | Intron (SNP) | VAF 14/108 reads (13%) | catalogued as rs1190336053; called by muse, mutect2
- CGB7 | c.-10C>T | 5'UTR (SNP) | VAF 53/290 reads (18%) | catalogued as rs751655312, COSV100655131; called by muse, mutect2, varscan2
- EPOR | c.*497C>T | 3'UTR (SNP) | VAF 73/329 reads (22%) | called by muse, mutect2, varscan2
- EYS | c.-23C>A | 5'UTR (SNP) | VAF 27/113 reads (24%) | catalogued as COSV100675539; called by muse, mutect2, varscan2
- KARS1 | c.62+45C>A | Intron (SNP) | VAF 76/327 reads (23%) | called by muse, mutect2, varscan2
- KLF6 | c.*1836T>C | 3'UTR (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2, varscan2
- KRT17P2 | n.311G>A | RNA (SNP) | VAF 39/319 reads (12%) | catalogued as rs1432370230; called by muse, mutect2, varscan2
- MICALL2 | c.641+47C>A | Intron (SNP) | VAF 66/489 reads (13%) | called by muse, varscan2
- PDLIM5 | c.921-6871C>A | Intron (SNP) | VAF 40/235 reads (17%) | called by muse, mutect2, varscan2
- SAP30BP | c.549+15C>T | Intron (SNP) | VAF 36/160 reads (23%) | catalogued as rs767048583; called by muse, mutect2, varscan2
- TPM1 | c.563+15C>T | Intron (SNP) | VAF 40/159 reads (25%) | catalogued as rs368177044; called by muse, mutect2, varscan2
- TTC7B | c.699-3626A>G | Intron (SNP) | VAF 33/176 reads (19%) | called by muse, mutect2, varscan2
- UBBP4 | n.454del | RNA (DEL) | VAF 34/179 reads (19%) | called by mutect2, pindel, varscan2
- ZAP70 | c.1082+34C>T | Intron (SNP) | VAF 36/143 reads (25%) | catalogued as rs1256273879; called by muse, mutect2, varscan2
